Somatic mutation profile of tumor specimen C3L-01884-02 (aliquot CPT0104360011) from CPTAC case C3L-01884, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 74.8 years (27,320 days).
Specimen C3L-01884-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e8340b4-3069-4671-90bc-bfba2c4ae156.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01884-31 (Blood Derived Normal), aliquot CPT0105120002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbc9505e-4bb4-43d7-85f9-8140452c0bdf

The open-access MAF lists 428 somatic variants for this specimen: 297 protein-altering or splice-affecting, 83 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 241, Silent 83, Intron 20, Frame Shift Del 16, Splice Site 16, Nonsense Mutation 15, RNA 9, 5'UTR 6, 3'Flank 5, 5'Flank 5, In Frame Del 4, Splice Region 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.528C>G p.C176W | Missense Mutation (SNP) | VAF 157/392 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519980, COSV52687391, COSV52701599, COSV52735850, COSV99377692; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCC10 | c.952G>A p.E318K (on ENST00000372530 / NM_001198934.2; = p.E275K on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/329 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs768502452; called by muse, mutect2, varscan2
- ADAMDEC1 | c.646del p.A216Hfs*23 | Frame Shift Del (DEL) | VAF 17/82 reads (21%) | catalogued as COSV99836254; called by mutect2, pindel*, varscan2
- AKAP8L | c.777G>A p.M259I | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.946); catalogued as rs1276302789; called by muse, mutect2, varscan2
- ANKRD24 | c.952G>T p.D318Y | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV53674018; called by muse, mutect2, varscan2
- ARFGEF1 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs1563894275; called by muse, mutect2, varscan2
- ARID1B | c.3971G>A p.R1324Q | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs761133847, COSV99269820; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASNS | c.1562T>G p.V521G | Missense Mutation (SNP) | VAF 61/373 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as rs746606098; called by muse, mutect2, varscan2
- ATG3 | c.320G>A p.W107* | Nonsense Mutation (SNP) | VAF 43/178 reads (24%) | catalogued as COSV51928099; called by muse, mutect2, varscan2
- ATP2C1 | c.1266G>T p.M422I | Missense Mutation (SNP) | VAF 80/306 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV60756018; called by muse, mutect2, varscan2
- ATP7A | c.1655G>T p.G552V | Missense Mutation (SNP) | VAF 83/166 reads (50%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV58455042; called by muse, mutect2, varscan2
- ATP9A | c.1442A>T p.Q481L | Missense Mutation (SNP) | VAF 104/466 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.091); catalogued as COSV58767629; called by muse, mutect2, varscan2
- BCL11B | c.825del p.Q276Sfs*5 (on ENST00000357195 / NM_001282237.2; = p.Q205Sfs*5 on NM_022898.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 30/133 reads (23%) | catalogued as COSV61739059; called by mutect2, pindel
- BLZF1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 16/65 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.838); catalogued as rs779814319, COSV61394191; called by muse, mutect2, varscan2
- C1RL | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 51/195 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as rs778893794, COSV56924791; called by muse, mutect2, varscan2
- CCDC141 | c.3776G>C p.G1259A | Missense Mutation (SNP) | VAF 127/373 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as COSV55382888; called by muse, mutect2, varscan2
- CCNE1 | c.846G>T p.L282F | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52904182; called by muse, mutect2, varscan2
- CECR2 | c.1205C>A p.A402E (on ENST00000342247 / NM_001290047.2; = p.A219E on NM_001290046.1) | Missense Mutation (SNP) | VAF 62/240 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52842532; called by muse, mutect2, varscan2
- CEP290 | c.3693G>T p.M1231I | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1221399740; called by muse, mutect2, varscan2
- CEP70 | c.1358A>G p.N453S | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.117); catalogued as rs1179911036, COSV99388734; called by muse, mutect2
- CFHR3 | c.740G>A p.G247D | Missense Mutation (SNP) | VAF 99/180 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs1380132180; called by muse, mutect2, varscan2
- CNTNAP2 | c.3010+1G>T p.X1004_splice | Splice Site (SNP) | VAF 62/173 reads (36%) | catalogued as COSV62183598; called by muse, mutect2, varscan2
- COL4A4 | c.1375T>C p.Y459H | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs765230841; called by muse, mutect2, varscan2
- CSMD3 | c.10965-1G>T p.X3655_splice (on ENST00000297405 / NM_001363185.1; = p.X3486_splice on NM_052900.3) | Splice Site (SNP) | VAF 62/224 reads (28%) | catalogued as COSV52147021, COSV52315905; called by muse, mutect2, varscan2
- DHRS7C | c.577G>T p.A193S (on ENST00000330255 / NM_001220493.2; = p.A192S on NM_001105571.3) | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV100364508, COSV100364616; called by muse, mutect2, varscan2
- DMD | c.5890G>T p.A1964S | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.804); catalogued as rs1325956986; called by muse, mutect2, varscan2
- DMGDH | c.1295A>G p.Y432C | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs747562067; called by muse, mutect2, varscan2
- DOP1A | c.5794A>G p.I1932V | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs761569853; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.877C>T p.L293F | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.755); catalogued as rs1406863153; called by muse, mutect2, varscan2
- ELOVL3 | c.114C>A p.F38L | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV64174568; called by muse, mutect2, varscan2
- EPHA3 | c.2753A>G p.D918G | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60728503; called by muse, mutect2
- EPHA6 | c.298G>T p.V100F | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.649); catalogued as COSV101061291; called by muse, mutect2, varscan2
- ERICH3 | c.168G>A p.M56I | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58599267, COSV58599999; called by muse, mutect2, varscan2
- EVI5L | c.1703G>T p.R568L | Missense Mutation (SNP) | VAF 115/528 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.641); catalogued as rs771498112; called by muse, mutect2, varscan2
- FAM229A | c.21_36del p.G8Qfs*40 | Frame Shift Del (DEL) | VAF 36/217 reads (17%) | catalogued as rs1271068449; called by mutect2, pindel
- FIBCD1 | c.1282C>T p.H428Y | Missense Mutation (SNP) | VAF 101/340 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs1363063913; called by muse, mutect2, varscan2
- FLG | c.6266C>G p.S2089C | Missense Mutation (SNP) | VAF 134/458 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV100911681; called by muse, mutect2, varscan2
- FLNA | c.1609G>C p.V537L | Missense Mutation (SNP) | VAF 185/351 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as rs782067087, COSV61039883; called by muse, mutect2, varscan2
- FREM3 | c.1964T>C p.L655P | Missense Mutation (SNP) | VAF 72/161 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs964306007; called by muse, mutect2, varscan2
- GNG5 | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 63/250 reads (25%) | catalogued as COSV55361646; called by muse, mutect2, varscan2
- GTPBP6 | c.1522G>T p.G508C | Missense Mutation (SNP) | VAF 112/371 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100397775; called by muse, mutect2, varscan2
- HHIPL2 | c.50C>A p.A17D | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.076); catalogued as rs953754351, COSV58564277; called by muse, mutect2, varscan2
- ITK | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 92/273 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101439585; called by muse, mutect2, varscan2
- KDM5B | c.2558C>T p.P853L | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1280245005; called by muse, mutect2, varscan2
- KDM6B | c.1286C>G p.A429G | Missense Mutation (SNP) | VAF 74/412 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV99641130; called by muse, mutect2, varscan2
- KIAA1841 | c.1584G>A p.W528* | Nonsense Mutation (SNP) | VAF 21/160 reads (13%) | catalogued as COSV54375323; called by muse, mutect2, varscan2
- KIR2DL4 | c.1106G>T p.C369F (on ENST00000396284; = p.C295F on NM_001080770.2) | Missense Mutation (SNP) | VAF 157/608 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs746058803, COSV58490117; called by muse, mutect2, varscan2
- KPNA1 | c.644C>G p.P215R | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs764664928; called by muse, mutect2, varscan2
- KRAS | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55570738; called by muse, mutect2, varscan2
- KRTAP19-5 | c.86G>T p.C29F | Missense Mutation (SNP) | VAF 172/590 reads (29%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.005); catalogued as COSV61859441; called by muse, mutect2, varscan2
- LAIR2 | c.417G>T p.G139= | Splice Region (SNP) | VAF 35/127 reads (28%) | catalogued as COSV56621191, COSV56621943; called by muse, mutect2, varscan2
- LRCH2 | c.1367A>G p.E456G | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.156); catalogued as rs1556543167; called by muse, mutect2
- LRRK2 | c.6159G>T p.Q2053H | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100109123; called by muse, mutect2, varscan2
- LRRTM4 | c.1047G>T p.K349N | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as rs1396648231, COSV101297750; called by muse, mutect2, varscan2
- MAGEA3 | c.702G>T p.R234S | Missense Mutation (SNP) | VAF 78/122 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV64756245; called by muse, mutect2, varscan2
- MAP3K21 | c.1432G>T p.E478* | Nonsense Mutation (SNP) | VAF 28/454 reads (6%) | catalogued as COSV100786308, COSV64043888; called by muse, mutect2
- METTL11B | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV63030129; called by muse, mutect2, varscan2
- MPZL3 | c.373A>G p.T125A | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1158560466; called by muse, mutect2, varscan2
- MYH6 | c.4828C>T p.R1610C | Missense Mutation (SNP) | VAF 141/595 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs780726611; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NADSYN1 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 111/390 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs1009622444; called by muse, varscan2
- NF1 | c.7682C>G p.S2561* (on ENST00000358273 / NM_001042492.3; = p.S2540* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 8/212 reads (4%) | catalogued as CM1512920, COSV104420544, COSV62201597; called by muse, mutect2
- NLGN4X | c.854C>A p.S285Y | Missense Mutation (SNP) | VAF 116/246 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52042225; called by muse, mutect2, varscan2
- NSD2 | c.274G>T p.G92C | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56392477; called by muse, mutect2, varscan2
- OR10T2 | c.580C>A p.H194N | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100555117, COSV57781484; called by muse, mutect2, varscan2
- OR11H4 | c.815C>G p.P272R | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59560902; called by muse, mutect2, varscan2
- OR8D4 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV58429312; called by muse, mutect2, varscan2
- PCLO | c.5482A>G p.S1828G | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1481066889; called by muse, mutect2, varscan2
- PDE10A | c.1735G>T p.D579Y | Missense Mutation (SNP) | VAF 104/420 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100604910; called by muse, mutect2, varscan2
- PIK3CD | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 55/339 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs755725121; called by muse, mutect2, varscan2
- PKD1L1 | c.2860C>A p.L954M | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV56970785; called by muse, mutect2, varscan2
- POMZP3 | c.66-1G>C p.X22_splice | Splice Site (SNP) | VAF 10/132 reads (8%) | catalogued as rs1372152588; called by muse, mutect2
- REG1B | c.232C>G p.Q78E | Missense Mutation (SNP) | VAF 72/291 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs752462312, COSV100521290; called by muse, mutect2, varscan2
- REV3L | c.3485C>G p.S1162C | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV100725454; called by muse, mutect2, varscan2
- RGPD3 | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58740962; called by muse, mutect2, varscan2
- ROBO1 | c.4795A>G p.R1599G | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.164); catalogued as rs1436562425; called by muse, mutect2, varscan2
- SART1 | c.839G>A p.G280D | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.969); catalogued as rs1012501272; called by muse, mutect2, varscan2
- SLC10A2 | c.241C>G p.L81V | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as COSV99807784; called by muse, mutect2, varscan2
- SLC39A12 | c.1349G>T p.G450V | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV66195203; called by muse, mutect2, varscan2
- SPAG8 | c.382A>G p.T128A | Missense Mutation (SNP) | VAF 56/244 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs374212595; called by muse, mutect2, varscan2
- TAAR8 | c.1007C>A p.T336N | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1490728775; called by muse, mutect2, varscan2
- TACC2 | c.353C>G p.P118R | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs376962666; called by muse, mutect2, varscan2
- TAF1L | c.3382C>A p.Q1128K | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as rs777714754; called by muse, mutect2, varscan2
- TIGIT | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 29/460 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs750928047; called by muse, mutect2
- TMCC3 | c.134G>C p.G45A | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs1437997800; called by muse, mutect2, varscan2
- TRIM35 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); catalogued as rs772787780; called by muse, mutect2
- TRIML2 | c.97G>T p.D33Y | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58717541; called by muse, mutect2, varscan2
- TTK | c.2561G>A p.R854K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.019); catalogued as rs539988632, COSV57886369; called by muse, varscan2
- VWA5B1 | c.1360del p.R454Efs*9 | Frame Shift Del (DEL) | VAF 133/549 reads (24%) | catalogued as COSV57057590; called by mutect2, pindel, varscan2
- WDR62 | c.1427C>T p.S476L | Missense Mutation (SNP) | VAF 117/521 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1194551869; called by muse, mutect2, varscan2
- ZNF10 | c.405G>C p.Q135H | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99940173; called by muse, mutect2, varscan2
- ZNF479 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58637132, COSV58642676; called by muse, mutect2, varscan2
- ZNF69 | c.662A>T p.K221I | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV100420973; called by muse, mutect2, varscan2
- ZNF831 | c.2488C>A p.L830M | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as COSV100925757; called by muse, mutect2, varscan2
- ABCB1 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- ACCSL | c.1615C>A p.L539I | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- ADAMTS14 | c.3388G>C p.A1130P | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ADAMTS3 | c.3586_3597del p.R1196_R1199del | In Frame Del (DEL) | VAF 8/44 reads (18%) | called by mutect2, pindel
- ADAMTS7 | c.311C>A p.P104H | Missense Mutation (SNP) | VAF 36/420 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAMTS9 | c.3196G>C p.V1066L | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- AGAP1 | c.1645+1G>T p.X549_splice (on ENST00000304032 / NM_001037131.3; = p.X496_splice on NM_014914.5) | Splice Site (SNP) | VAF 13/291 reads (4%) | called by muse, mutect2
- AGTR1 | c.595A>C p.K199Q | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALG13 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AMER3 | c.1669del p.A557Rfs*127 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- AMIGO1 | c.805A>T p.N269Y | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ANGPTL6 | c.385G>C p.G129R | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- ANKRD24 | c.952-1G>T p.X318_splice | Splice Site (SNP) | VAF 19/68 reads (28%) | called by muse, mutect2, varscan2
- AP2A1 | c.995A>G p.N332S | Missense Mutation (SNP) | VAF 84/300 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- APC2 | c.3622C>G p.P1208A | Missense Mutation (SNP) | VAF 72/267 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ARHGAP21 | c.2645A>G p.Y882C | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ARHGAP35 | c.3782T>C p.I1261T | Missense Mutation (SNP) | VAF 52/209 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARID1A | c.5954C>T p.S1985F | Missense Mutation (SNP) | VAF 39/299 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARTN | c.44C>G p.P15R | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ASMT | c.730G>T p.E244* (on ENST00000381229; = p.E272* on NM_004043.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 162/471 reads (34%) | called by muse, mutect2, varscan2
- ATIC | c.1009-2A>T p.X337_splice | Splice Site (SNP) | VAF 28/85 reads (33%) | called by muse, mutect2, varscan2
- BCHE | c.1404T>A p.Y468* | Nonsense Mutation (SNP) | VAF 23/132 reads (17%) | called by muse, mutect2, varscan2
- BRCA2 | c.3608del p.S1203Mfs*6 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | called by mutect2, pindel, varscan2
- C11orf54 | c.817C>T p.H273Y (on ENST00000331239; = p.H223Y on NM_014039.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- C7orf31 | c.860-1G>T p.X287_splice | Splice Site (SNP) | VAF 19/84 reads (23%) | called by muse, mutect2, varscan2
- CACNA1G | c.1191G>C p.Q397H | Missense Mutation (SNP) | VAF 17/202 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- CACNA2D1 | c.1799T>C p.I600T (on ENST00000356253 / NM_001366867.1; = p.I581T on NM_000722.4) | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2
- CAMTA2 | c.2423G>C p.C808S | Missense Mutation (SNP) | VAF 103/381 reads (27%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- CCDC141 | c.4182C>A p.S1394R | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CCDC27 | c.312del p.K105Rfs*105 | Frame Shift Del (DEL) | VAF 38/124 reads (31%) | called by mutect2, pindel, varscan2
- CDH12 | c.397G>T p.D133Y | Missense Mutation (SNP) | VAF 52/349 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP112 | c.401_419del p.L134Sfs*9 | Frame Shift Del (DEL) | VAF 31/115 reads (27%) | called by mutect2, pindel, varscan2
- CFAP61 | c.3179C>G p.P1060R | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- CFH | c.2102G>T p.W701L | Missense Mutation (SNP) | VAF 56/219 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CLEC12A | c.484G>T p.A162S | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CMTM7 | c.211T>G p.Y71D | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- CNGB3 | c.2000C>A p.P667Q | Missense Mutation (SNP) | VAF 89/386 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- COL24A1 | c.4682G>A p.W1561* | Nonsense Mutation (SNP) | VAF 39/129 reads (30%) | called by muse, mutect2, varscan2
- COL24A1 | c.57-1G>A p.X19_splice | Splice Site (SNP) | VAF 16/95 reads (17%) | called by muse, mutect2, varscan2
- CPNE7 | c.592C>G p.Q198E | Missense Mutation (SNP) | VAF 93/391 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- CSGALNACT2 | c.1280G>C p.W427S | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CSMD2 | c.5281T>C p.C1761R | Missense Mutation (SNP) | VAF 106/622 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.10965G>T p.R3655S (on ENST00000297405 / NM_001363185.1; = p.R3486S on NM_052900.3) | Missense Mutation (SNP) | VAF 62/224 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CST5 | c.351G>C p.E117D | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- CUBN | c.7457A>G p.E2486G | Missense Mutation (SNP) | VAF 88/347 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- CYP2A13 | c.222del p.R76Gfs*60 | Frame Shift Del (DEL) | VAF 85/330 reads (26%) | called by mutect2, pindel, varscan2
- DBH | c.1309G>C p.D437H | Missense Mutation (SNP) | VAF 130/380 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCTN1 | c.2294G>C p.G765A | Missense Mutation (SNP) | VAF 57/734 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, mutect2
- DDC | c.201+1G>T p.X67_splice | Splice Site (SNP) | VAF 121/518 reads (23%) | called by muse, mutect2, varscan2
- DDX10 | c.232A>G p.K78E | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- DDX21 | c.129G>C p.E43D | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.101); called by muse, mutect2
- DEF8 | c.367G>C p.D123H (on ENST00000268676 / NM_207514.3; = p.D62H on NM_017702.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/519 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- DENND4C | c.3618G>C p.E1206D (on ENST00000434457 / NM_001330640.2; = p.E1157D on NM_017925.7) | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- DNAH5 | c.5048A>T p.E1683V | Missense Mutation (SNP) | VAF 56/236 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DUSP16 | c.1698C>G p.F566L | Missense Mutation (SNP) | VAF 87/336 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM120C | c.1802C>T p.P601L | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FANCD2 | c.1322G>T p.S441I | Missense Mutation (SNP) | VAF 106/613 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- FARP1 | c.2920G>T p.A974S | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT2 | c.6230_6235del p.T2077_I2078del | In Frame Del (DEL) | VAF 42/103 reads (41%) | called by mutect2, pindel, varscan2
- FAT2 | c.5831_5840dup p.L1947Ffs*2 | Nonsense Mutation (INS) | VAF 30/109 reads (28%) | called by mutect2, varscan2
- FBP1 | c.463C>A p.Q155K | Missense Mutation (SNP) | VAF 92/363 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- FCRL1 | c.819C>A p.N273K | Missense Mutation (SNP) | VAF 55/193 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FLRT2 | c.1432C>A p.L478M | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- FLT3 | c.2934G>T p.E978D | Missense Mutation (SNP) | VAF 72/238 reads (30%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- FMN1 | c.2324A>G p.H775R (on ENST00000616417 / NM_001277313.2; = p.H552R on NM_001103184.4) | Missense Mutation (SNP) | VAF 66/196 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FNDC3A | c.2068G>A p.G690S (on ENST00000492622 / NM_001079673.2; = p.G634S on NM_014923.5) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- FOXR2 | c.58G>T p.G20W | Missense Mutation (SNP) | VAF 47/65 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GAB4 | c.1447G>T p.E483* | Nonsense Mutation (SNP) | VAF 51/164 reads (31%) | called by muse, mutect2, varscan2
- GABRA4 | c.205+1del p.X69_splice | Splice Site (DEL) | VAF 17/98 reads (17%) | called by mutect2, pindel, varscan2
- GCN1 | c.2420A>T p.E807V | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- GDAP1 | c.311-2A>G p.X104_splice | Splice Site (SNP) | VAF 72/253 reads (28%) | called by muse, mutect2, varscan2
- GHRHR | c.969G>C p.Q323H | Missense Mutation (SNP) | VAF 70/272 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- GLI2 | c.1505A>G p.N502S (on ENST00000361492 / NM_001374353.1; = p.N519S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- GPR158 | c.2515C>A p.Q839K | Missense Mutation (SNP) | VAF 60/229 reads (26%) | SIFT tolerated (0.92); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GRHL2 | c.661A>G p.K221E | Missense Mutation (SNP) | VAF 155/410 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- GRK4 | c.991C>A p.L331I (on ENST00000398052 / NM_182982.3; = p.L299I on NM_005307.3) | Missense Mutation (SNP) | VAF 85/296 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- HID1 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 150/263 reads (57%) | called by muse, mutect2, varscan2
- HOXA11 | c.472G>C p.D158H | Missense Mutation (SNP) | VAF 161/602 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- IGKV1-17 | c.271A>T p.T91S | Missense Mutation (SNP) | VAF 50/452 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.812); called by muse, varscan2
- IGKV1D-12 | c.83A>T p.Q28L | Missense Mutation (SNP) | VAF 34/253 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- IGKV6-21 | c.54G>T p.R18S | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.92); PolyPhen benign (0.01); called by mutect2, varscan2
- KCNK18 | c.381G>T p.R127S | Missense Mutation (SNP) | VAF 78/388 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, varscan2
- KCTD18 | c.36T>A p.D12E | Missense Mutation (SNP) | VAF 96/216 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- KIF21A | c.1613T>C p.I538T | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- KIR2DL3 | c.173T>A p.F58Y | Missense Mutation (SNP) | VAF 102/338 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- KLHL22 | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 18/342 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.406); called by muse, mutect2
- KMT2A | c.2593G>C p.D865H | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- KRTAP5-11 | c.56C>A p.S19Y | Missense Mutation (SNP) | VAF 33/310 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- KRTAP5-6 | c.181G>T p.G61C | Missense Mutation (SNP) | VAF 126/359 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LCOR | c.1268G>T p.W423L | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.976); called by muse, mutect2
- LGSN | c.595G>T p.G199C | Missense Mutation (SNP) | VAF 52/203 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LPIN2 | c.2405A>T p.K802M | Missense Mutation (SNP) | VAF 92/393 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- LPIN3 | c.1142T>C p.I381T | Missense Mutation (SNP) | VAF 25/293 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- LRP1 | c.1906G>A p.A636T | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.223); called by muse, mutect2
- LRTM1 | c.839C>G p.A280G | Missense Mutation (SNP) | VAF 35/447 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.276); called by muse, mutect2
- LYST | c.1444A>G p.T482A | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- MAP3K12 | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAP3K21 | c.1433A>T p.E478V | Missense Mutation (SNP) | VAF 28/456 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MBD5 | c.2124G>A p.M708I | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- MCM4 | c.2449G>A p.A817T | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- MED23 | c.3622A>G p.T1208A | Missense Mutation (SNP) | VAF 88/306 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MGAT4C | c.1268G>A p.R423K | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- MIEF2 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- MIIP | c.734T>C p.V245A | Missense Mutation (SNP) | VAF 37/227 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- MPPED1 | c.471G>T p.E157D | Missense Mutation (SNP) | VAF 77/282 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MTHFD1L | c.2224_2230del p.A742Cfs*4 | Frame Shift Del (DEL) | VAF 30/164 reads (18%) | called by mutect2, pindel, varscan2
- MUC16 | c.22245C>A p.S7415R | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- MYH2 | c.499C>A p.L167M | Missense Mutation (SNP) | VAF 117/353 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- NAE1 | c.1367A>C p.K456T | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- NDUFA4 | c.188A>G p.K63R | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NEUROG1 | c.180G>T p.E60D | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- NF1 | c.1339_1355del p.L447Rfs*17 | Frame Shift Del (DEL) | VAF 49/248 reads (20%) | called by mutect2, pindel, varscan2
- NOTCH3 | c.1442G>T p.G481V | Missense Mutation (SNP) | VAF 163/578 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- NRL | c.554G>C p.R185P | Missense Mutation (SNP) | VAF 80/354 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- NRXN2 | c.1527G>C p.W509C | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NTNG1 | c.1342A>T p.K448* | Nonsense Mutation (SNP) | VAF 19/130 reads (15%) | called by muse, mutect2, varscan2
- NTRK3 | c.2267T>A p.F756Y (on ENST00000360948 / NM_001012338.2; = p.F742Y on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/352 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- NUBPL | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- NUP98 | c.2417A>T p.N806I | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- NUTM2E | c.1977C>A p.D659E | Missense Mutation (SNP) | VAF 24/433 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.037); called by muse, mutect2
- OR2AK2 | c.929G>T p.C310F | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR5L2 | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- OR6F1 | c.378C>G p.I126M | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- OTOG | c.1984G>T p.D662Y | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OXR1 | c.2401T>C p.C801R (on ENST00000442977 / NM_001198532.1; = p.C773R on NM_018002.3) | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- P2RY1 | c.304C>G p.L102V | Missense Mutation (SNP) | VAF 24/501 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.892); called by muse, mutect2
- P4HA3 | c.1024A>C p.I342L | Missense Mutation (SNP) | VAF 45/249 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDH17 | c.2242A>T p.S748C | Missense Mutation (SNP) | VAF 84/269 reads (31%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PCDHB11 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PEX11A | c.698G>C p.G233A | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- PHLDB3 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 51/285 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PJVK | c.568C>A p.Q190K | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PKP2 | c.386A>T p.Q129L | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PLPPR4 | c.97G>C p.V33L | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLXNB1 | c.503_509del p.V168Efs*50 | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | called by mutect2, pindel, varscan2
- PNLDC1 | c.571C>T p.L191F | Missense Mutation (SNP) | VAF 20/366 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.112); called by muse, mutect2
- POF1B | c.249_253del p.Y84Kfs*33 | Frame Shift Del (DEL) | VAF 34/74 reads (46%) | called by mutect2, pindel
- PPP4R3C | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- PRKG1 | c.106G>C p.D36H | Missense Mutation (SNP) | VAF 23/385 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.695); called by muse, mutect2
- PRMT6 | c.724T>C p.S242P | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRODH2 | c.1264G>C p.V422L (on ENST00000301175; = p.V346L on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- PRPF38B | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRR23A | c.106G>T p.G36C | Missense Mutation (SNP) | VAF 70/314 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PSG2 | c.933A>T p.E311D | Missense Mutation (SNP) | VAF 97/319 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- PTPN3 | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- RASA1 | c.2345-3_2347del p.X782_splice | Splice Site (DEL) | VAF 26/110 reads (24%) | called by mutect2, pindel, varscan2
- RGR | c.137A>T p.E46V | Missense Mutation (SNP) | VAF 28/566 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); called by muse, mutect2
- RGS6 | c.854+1G>T p.X285_splice | Splice Site (SNP) | VAF 21/99 reads (21%) | called by muse, mutect2, varscan2
- RPS12 | c.331_333del p.V111del | In Frame Del (DEL) | VAF 18/88 reads (20%) | called by mutect2, pindel, varscan2
- RPS27 | c.221C>A p.T74K | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.075); called by muse, mutect2
- RRBP1 | c.2325G>T p.Q775H (on ENST00000377813 / NM_001365613.2; = p.Q342H on NM_004587.3) | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- RSPH4A | c.512C>A p.A171D | Missense Mutation (SNP) | VAF 52/205 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- RTF1 | c.1513G>C p.A505P | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- RYR2 | c.13052G>A p.R4351K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- SACS | c.3385A>G p.K1129E | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SCAF11 | c.1498A>G p.I500V | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCGN | c.365G>C p.S122T | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SCN10A | c.1303C>A p.L435I | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- SEMA3C | c.283A>G p.T95A | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- SH3TC2 | c.3053+8A>T | Splice Region (SNP) | VAF 70/177 reads (40%) | called by muse, mutect2, varscan2
- SI | c.2966G>T p.R989L | Missense Mutation (SNP) | VAF 35/241 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SLC25A32 | c.667-1G>T p.X223_splice | Splice Site (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- SLC25A38 | c.119G>C p.C40S | Missense Mutation (SNP) | VAF 139/381 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- SLC35D3 | c.869A>G p.N290S | Missense Mutation (SNP) | VAF 123/470 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SLC38A8 | c.656_662del p.F219Sfs*47 | Frame Shift Del (DEL) | VAF 31/174 reads (18%) | called by mutect2, pindel, varscan2
- SLC39A14 | c.230A>T p.N77I | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- SLC5A9 | c.1340T>A p.I447N | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- SOCS6 | c.1222G>T p.V408F | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SOX21 | c.625G>T p.A209S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- SUOX | c.317C>G p.S106C | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SYNE1 | c.20332A>C p.S6778R (on ENST00000367255 / NM_182961.4; = p.S6707R on NM_033071.3) | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- SYNE2 | c.6374_6376del p.N2125del | In Frame Del (DEL) | VAF 70/508 reads (14%) | called by pindel, varscan2
- TEKT4 | c.1257G>C p.M419I | Missense Mutation (SNP) | VAF 92/387 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- TEX51 | c.467-1G>A p.X156_splice (on ENST00000643416; = p.X132_splice on NM_001322244.2) | Splice Site (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- THEMIS | c.1005del p.T336Lfs*20 | Frame Shift Del (DEL) | VAF 34/177 reads (19%) | called by mutect2, pindel, varscan2
- TLL2 | c.301C>A p.Q101K | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLR5 | c.1000G>T p.G334* | Nonsense Mutation (SNP) | VAF 73/330 reads (22%) | called by muse, mutect2, varscan2
- TMC6 | c.2278-4C>G | Splice Region (SNP) | VAF 49/562 reads (9%) | called by muse, mutect2
- TMEM185A | c.972G>T p.K324N | Missense Mutation (SNP) | VAF 133/456 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- TONSL | c.4004G>C p.R1335P | Missense Mutation (SNP) | VAF 54/222 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- TRIM44 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM56 | c.941G>C p.S314T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.067); called by muse, mutect2
- TRIP12 | c.2081T>C p.I694T | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- TRPM4 | c.623C>G p.P208R | Missense Mutation (SNP) | VAF 34/708 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- TTLL8 | c.2466G>C p.K822N | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TTN | c.1393G>C p.E465Q | Missense Mutation (SNP) | VAF 172/513 reads (34%) | PolyPhen benign (0.093); called by muse, mutect2, varscan2
- TUBB1 | c.1073C>A p.P358H | Missense Mutation (SNP) | VAF 136/556 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- UBE3D | c.970A>G p.K324E | Missense Mutation (SNP) | VAF 58/222 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- UBR5 | c.5215+1del p.X1739_splice | Splice Site (DEL) | VAF 82/248 reads (33%) | called by mutect2, pindel
- ULBP2 | c.24G>C p.K8N | Missense Mutation (SNP) | VAF 7/182 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.055); called by muse, mutect2
- USH1C | c.602C>A p.S201Y | Missense Mutation (SNP) | VAF 200/534 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- USH2A | c.5816C>A p.S1939* | Nonsense Mutation (SNP) | VAF 50/265 reads (19%) | called by muse, mutect2, varscan2
- UTRN | c.6406C>T p.L2136F | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, varscan2
- VEPH1 | c.1204C>T p.H402Y | Missense Mutation (SNP) | VAF 57/369 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- WDR19 | c.1417G>T p.D473Y | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- WDR72 | c.526T>A p.L176M | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- WWC2 | c.3144G>C p.T1048= | Splice Region (SNP) | VAF 51/114 reads (45%) | called by muse, varscan2
- ZC3H6 | c.2632G>T p.V878L | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- ZNF202 | c.1885del p.S629Afs*8 | Frame Shift Del (DEL) | VAF 42/131 reads (32%) | called by mutect2, pindel, varscan2
- ZNF532 | c.3231G>T p.K1077N | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZNF705G | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 49/287 reads (17%) | called by muse, mutect2, varscan2
- ZNF705G | c.54G>T p.Q18H | Missense Mutation (SNP) | VAF 49/283 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF778 | c.158A>T p.Q53L | Missense Mutation (SNP) | VAF 66/262 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- ZNF831 | c.2487C>A p.D829E | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCD4 | c.291G>A p.K97= | Silent (SNP) | VAF 51/255 reads (20%) | called by muse, mutect2, varscan2
- ADAM33 | c.492C>T p.H164= | Silent (SNP) | VAF 42/213 reads (20%) | catalogued as rs753262884, COSV62936839; called by muse, mutect2, varscan2
- ADCY6 | c.1746G>T p.P582= | Silent (SNP) | VAF 133/548 reads (24%) | called by muse, mutect2, varscan2
- ANAPC1 | c.5715A>G p.L1905= | Silent (SNP) | VAF 41/231 reads (18%) | called by muse, mutect2, varscan2
- ANOS1 | c.1281C>G p.R427= | Silent (SNP) | VAF 92/189 reads (49%) | called by muse, mutect2, varscan2
- BCORL1 | c.3600C>T p.H1200= | Silent (SNP) | VAF 86/198 reads (43%) | catalogued as rs746692970; called by muse, mutect2, varscan2
- BICC1 | c.1566T>C p.T522= | Silent (SNP) | VAF 18/52 reads (35%) | called by muse, varscan2
- BMP3 | c.1344A>G p.L448= | Silent (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
- C3orf22 | c.267A>G p.L89= | Silent (SNP) | VAF 65/293 reads (22%) | called by muse, mutect2, varscan2
- CELSR1 | c.7956C>T p.S2652= | Silent (SNP) | VAF 51/234 reads (22%) | catalogued as COSV53088251; called by muse, mutect2, varscan2
- CHD2 | c.3930A>G p.L1310= | Silent (SNP) | VAF 171/283 reads (60%) | catalogued as rs937962317; called by muse, mutect2, varscan2
- CHIC2 | c.258A>T p.L86= | Silent (SNP) | VAF 34/118 reads (29%) | called by muse, mutect2, varscan2
- CLCN4 | c.1023C>T p.F341= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as rs1446291730, COSV66467298; called by muse, mutect2, varscan2
- CNIH1 | c.63C>T p.I21= | Silent (SNP) | VAF 73/362 reads (20%) | called by muse, mutect2, varscan2
- COG2 | c.306T>A p.L102= | Silent (SNP) | VAF 22/97 reads (23%) | called by muse, mutect2, varscan2
- CPB1 | c.828C>A p.A276= | Silent (SNP) | VAF 55/363 reads (15%) | catalogued as rs146059086; called by muse, mutect2, varscan2
- DLC1 | c.183A>G p.L61= | Silent (SNP) | VAF 49/117 reads (42%) | called by muse, mutect2, varscan2
- DLGAP1 | c.2256C>A p.A752= | Silent (SNP) | VAF 66/244 reads (27%) | called by muse, mutect2, varscan2
- DMD | c.7377A>G p.L2459= | Silent (SNP) | VAF 51/99 reads (52%) | called by muse, mutect2, varscan2
- DMRTA1 | c.1155A>T p.T385= | Silent (SNP) | VAF 70/212 reads (33%) | called by muse, mutect2, varscan2
- DNAH10 | c.8394T>C p.A2798= (on ENST00000409039; = p.A2737= on NM_207437.3) | Silent (SNP) | VAF 38/221 reads (17%) | catalogued as rs758715908; called by muse, mutect2, varscan2
- DPPA5 | c.198C>G p.T66= | Silent (SNP) | VAF 82/332 reads (25%) | catalogued as rs550609190, COSV64876039; called by muse, mutect2, varscan2
- ENPP6 | c.735C>T p.D245= | Silent (SNP) | VAF 121/280 reads (43%) | catalogued as rs377226218; called by muse, mutect2, varscan2
- FAM193A | c.801C>T p.G267= | Silent (SNP) | VAF 106/432 reads (25%) | called by muse, mutect2, varscan2
- FCRL1 | c.381A>T p.G127= | Silent (SNP) | VAF 67/203 reads (33%) | catalogued as rs898011828; called by muse, mutect2, varscan2
- FERD3L | c.63C>T p.S21= | Silent (SNP) | VAF 32/138 reads (23%) | catalogued as rs1277474223; called by muse, mutect2, varscan2
- FTMT | c.336C>T p.S112= | Silent (SNP) | VAF 51/180 reads (28%) | catalogued as COSV58420777; called by muse, mutect2, varscan2
- FURIN | c.150G>C p.R50= | Silent (SNP) | VAF 40/229 reads (17%) | called by muse, mutect2, varscan2
- GPR37L1 | c.159C>A p.A53= | Silent (SNP) | VAF 84/282 reads (30%) | called by muse, mutect2, varscan2
- GPRC5D | c.531C>A p.V177= | Silent (SNP) | VAF 29/124 reads (23%) | called by muse, mutect2, varscan2
- GSTM2 | c.198G>T p.G66= | Silent (SNP) | VAF 79/362 reads (22%) | called by muse, mutect2, varscan2
- H6PD | c.1359G>T p.R453= | Silent (SNP) | VAF 210/967 reads (22%) | called by muse, mutect2, varscan2
- IGHG4 | c.540C>T p.Y180= | Silent (SNP) | VAF 163/1022 reads (16%) | called by muse, mutect2, varscan2
- ITIH2 | c.702C>T p.F234= | Silent (SNP) | VAF 25/202 reads (12%) | catalogued as rs148694864; called by muse, mutect2, varscan2
- KCNT1 | c.78C>T p.T26= | Silent (SNP) | VAF 119/411 reads (29%) | catalogued as rs1432472367; called by muse, mutect2, varscan2
- KIF26A | c.3438C>A p.P1146= | Silent (SNP) | VAF 92/187 reads (49%) | called by muse, mutect2, varscan2
- MACF1 | c.1683T>G p.S561= | Silent (SNP) | VAF 75/349 reads (21%) | called by muse, mutect2, varscan2
- MAPK8IP2 | c.1200C>T p.A400= | Silent (SNP) | VAF 10/19 reads (53%) | called by muse, mutect2, varscan2
- MEP1B | c.1182G>C p.V394= | Silent (SNP) | VAF 25/127 reads (20%) | catalogued as COSV52496227; called by muse, mutect2, varscan2
- MUC4 | c.11106T>A p.P3702= | Silent (SNP) | VAF 130/656 reads (20%) | called by muse, varscan2
- NADSYN1 | c.789G>T p.L263= | Silent (SNP) | VAF 114/392 reads (29%) | called by muse, varscan2
- NCKAP5 | c.2847A>T p.P949= | Silent (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- NDUFB8 | c.57G>T p.R19= | Silent (SNP) | VAF 18/354 reads (5%) | catalogued as COSV54511708, COSV54512682; called by muse, mutect2
- NOP58 | c.1122T>C p.A374= | Silent (SNP) | VAF 18/148 reads (12%) | called by muse, mutect2, varscan2
- NOTCH1 | c.7605C>T p.G2535= | Silent (SNP) | VAF 111/284 reads (39%) | catalogued as rs757253280, COSV99491296; called by muse, mutect2, varscan2
- OLFM3 | c.534G>A p.R178= (on ENST00000338858 / NM_001288821.1; = p.R158= on NM_058170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/201 reads (19%) | called by muse, mutect2, varscan2
- OR10K2 | c.621G>T p.L207= | Silent (SNP) | VAF 56/249 reads (22%) | catalogued as rs763063679; called by muse, mutect2, varscan2
- PCDHGA3 | c.1509C>G p.S503= | Silent (SNP) | VAF 20/196 reads (10%) | catalogued as COSV99543185; called by muse, mutect2
- PCSK5 | c.4716C>T p.S1572= | Silent (SNP) | VAF 74/246 reads (30%) | catalogued as rs941108836; called by muse, mutect2, varscan2
- PIRT | c.213C>T p.V71= | Silent (SNP) | VAF 58/134 reads (43%) | called by muse, mutect2, varscan2
- PKD1L3 | c.5091G>A p.Q1697= | Silent (SNP) | VAF 50/160 reads (31%) | catalogued as COSV58666237; called by muse, mutect2, varscan2
- POLQ | c.2106A>G p.V702= | Silent (SNP) | VAF 48/161 reads (30%) | called by muse, mutect2, varscan2
- POU6F2 | c.1062G>C p.G354= | Silent (SNP) | VAF 58/216 reads (27%) | called by mutect2, varscan2
- PROCA1 | c.741G>A p.E247= (on ENST00000439862 / NM_001366301.1; = p.E219= on NM_152465.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 61/194 reads (31%) | called by muse, mutect2, varscan2
- RADIL | c.3225C>G p.L1075= | Silent (SNP) | VAF 56/187 reads (30%) | catalogued as COSV68200935; called by muse, mutect2, varscan2
- RDM1 | c.699C>G p.P233= | Silent (SNP) | VAF 52/111 reads (47%) | called by muse, mutect2, varscan2
- SHOX2 | c.132C>A p.T44= | Silent (SNP) | VAF 100/442 reads (23%) | called by muse, mutect2, varscan2
- SHROOM3 | c.921C>G p.V307= | Silent (SNP) | VAF 14/246 reads (6%) | called by muse, mutect2
- SLC22A24 | c.1176C>G p.A392= | Silent (SNP) | VAF 28/289 reads (10%) | called by muse, mutect2
- SLC30A10 | c.669A>G p.P223= | Silent (SNP) | VAF 10/244 reads (4%) | catalogued as rs1202377144; called by muse, mutect2
- SLITRK2 | c.1962C>A p.P654= | Silent (SNP) | VAF 42/74 reads (57%) | called by muse, mutect2, varscan2
- SNX9 | c.423C>G p.P141= | Silent (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2, varscan2
- SPTBN2 | c.2487C>A p.T829= | Silent (SNP) | VAF 16/223 reads (7%) | called by muse, mutect2
- SRRM1 | c.942G>T p.R314= | Silent (SNP) | VAF 44/156 reads (28%) | called by muse, mutect2, varscan2
- STON1 | c.2043T>C p.C681= | Silent (SNP) | VAF 17/367 reads (5%) | called by muse, mutect2
- STXBP6 | c.517T>C p.L173= | Silent (SNP) | VAF 57/228 reads (25%) | called by muse, mutect2, varscan2
- SYNGAP1 | c.1549C>T p.L517= | Silent (SNP) | VAF 59/199 reads (30%) | called by muse, mutect2, varscan2
- SYT16 | c.588A>G p.K196= | Silent (SNP) | VAF 18/249 reads (7%) | called by muse, mutect2
- THNSL1 | c.1158C>A p.V386= | Silent (SNP) | VAF 24/87 reads (28%) | called by muse, mutect2, varscan2
- TMEM132C | c.2085G>T p.V695= | Silent (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2, varscan2
- TRIM56 | c.78G>A p.E26= | Silent (SNP) | VAF 79/402 reads (20%) | called by muse, mutect2, varscan2
- TSSK3 | c.81A>G p.A27= | Silent (SNP) | VAF 37/178 reads (21%) | called by muse, mutect2, varscan2
- UBR3 | c.405G>T p.T135= | Silent (SNP) | VAF 52/225 reads (23%) | called by muse, mutect2, varscan2
- UBR4 | c.3834G>A p.L1278= | Silent (SNP) | VAF 25/133 reads (19%) | called by muse, mutect2, varscan2
- VWA3B | c.795C>T p.V265= | Silent (SNP) | VAF 49/237 reads (21%) | called by muse, mutect2, varscan2
- ZBTB11 | c.2106A>G p.Q702= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as rs772819657, COSV57244390; called by muse, mutect2, varscan2
- ZEB1 | c.1143A>G p.L381= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as rs1158818141; called by muse, mutect2, varscan2
- ZFHX4 | c.750C>G p.S250= | Silent (SNP) | VAF 44/151 reads (29%) | called by muse, mutect2, varscan2
- ZNF317 | c.1071G>T p.T357= | Silent (SNP) | VAF 60/258 reads (23%) | catalogued as rs763229027, COSV56109326; called by muse, mutect2, varscan2
- ZNF415 | c.1065T>G p.P355= | Silent (SNP) | VAF 31/116 reads (27%) | called by muse, mutect2, varscan2
- ZNF536 | c.2724G>T p.V908= | Silent (SNP) | VAF 51/207 reads (25%) | called by muse, mutect2, varscan2
- ZNF676 | c.147G>A p.K49= (on ENST00000650058; = p.K17= on NM_001001411.3) | Silent (SNP) | VAF 20/75 reads (27%) | called by muse, mutect2, varscan2
- ZNF787 | c.690C>T p.D230= | Silent (SNP) | VAF 44/163 reads (27%) | catalogued as rs1428354517; called by muse, mutect2, varscan2
- ABCC2 | c.-48C>A | 5'UTR (SNP) | VAF 25/110 reads (23%) | called by muse, mutect2, varscan2
- AC106038.2 | chr8:90703449 G>A | 3'Flank (SNP) | VAF 9/82 reads (11%) | catalogued as rs565378753, COSV72905825; called by muse, mutect2, varscan2
- ADA | c.362+23del | Intron (DEL) | VAF 83/448 reads (19%) | called by mutect2, pindel, varscan2
- ADAMTS10 | c.1190+40C>A | Intron (SNP) | VAF 112/379 reads (30%) | called by muse, mutect2, varscan2
- AMPH | c.1182+701A>C | Intron (SNP) | VAF 30/128 reads (23%) | called by muse, mutect2, varscan2
- ASTN1 | chr1:176857605 C>T | 3'Flank (SNP) | VAF 10/31 reads (32%) | called by muse, mutect2, varscan2
- BDKRB2 | c.-136C>G | 5'UTR (SNP) | VAF 17/62 reads (27%) | called by muse, mutect2, varscan2
- C17orf49 | chr17:7017529 del CTGTCTGCTTAACATTATTAGCAGGAGAGGC | 3'Flank (DEL) | VAF 24/141 reads (17%) | called by mutect2, pindel
- C3orf33 | c.114+481C>T | Intron (SNP) | VAF 145/424 reads (34%) | called by muse, mutect2, varscan2
- CCDC12 | c.306+34C>T | Intron (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- CMIP | c.1481+35G>T | Intron (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- CPAMD8 | c.5568-1065C>T | Intron (SNP) | VAF 10/222 reads (5%) | called by muse, mutect2
- DCAF13 | chr8:103415354 ins T | 5'Flank (INS) | VAF 87/455 reads (19%) | called by mutect2, pindel, varscan2
- DDX11 | c.2052+50G>C | Intron (SNP) | VAF 47/275 reads (17%) | catalogued as rs756365049; called by muse, mutect2, varscan2
- DEFB114 | c.-4C>A | 5'UTR (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- FTH1 | c.-24C>G | 5'UTR (SNP) | VAF 94/459 reads (20%) | called by mutect2, varscan2
- HLA-DPB2 | n.364C>T | RNA (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- HNRNPA2B1 | c.7-9T>C | Intron (SNP) | VAF 12/78 reads (15%) | catalogued as rs773972068, COSV61159208; ClinVar: likely benign; called by mutect2, varscan2
- IGKV1-13 | n.20C>A | RNA (SNP) | VAF 25/176 reads (14%) | called by muse, mutect2, varscan2
- KLRA1P | n.659A>C | RNA (SNP) | VAF 32/134 reads (24%) | called by muse, mutect2, varscan2
- KRT86 | c.-6dup | 5'UTR (INS) | VAF 171/751 reads (23%) | called by mutect2, pindel, varscan2
- MUC19 | n.5303A>G | RNA (SNP) | VAF 37/113 reads (33%) | called by muse, mutect2, varscan2
- MYH7 | c.4169+160C>A | Intron (SNP) | VAF 28/144 reads (19%) | called by muse, mutect2, varscan2
- Metazoa_SRP | chr17:18610101 C>A | 5'Flank (SNP) | VAF 46/520 reads (9%) | called by muse, mutect2
- OR7E5P | n.309G>T | RNA (SNP) | VAF 57/250 reads (23%) | called by muse, mutect2, varscan2
- OVCH1 | c.2125+25C>G | Intron (SNP) | VAF 28/117 reads (24%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141156475 T>A | 3'Flank (SNP) | VAF 57/162 reads (35%) | called by muse, mutect2, varscan2
- PHF20 | c.-8G>A | 5'UTR (SNP) | VAF 10/114 reads (9%) | called by muse, mutect2
- PIEZO1 | c.161-854G>C | Intron (SNP) | VAF 41/251 reads (16%) | catalogued as rs898567787; called by muse, mutect2, varscan2
- RAB24 | c.485-18C>T | Intron (SNP) | VAF 25/239 reads (10%) | called by muse, mutect2, varscan2
- RANBP1 | c.310+242_310+252del | Intron (DEL) | VAF 60/212 reads (28%) | called by mutect2, pindel
- RPS4XP21 | n.183G>T | RNA (SNP) | VAF 64/332 reads (19%) | called by muse, mutect2, varscan2
- SLC25A23 | chr19:6438780 C>G | 3'Flank (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2
- SLC25A29 | chr14:100307915 C>A | 5'Flank (SNP) | VAF 19/127 reads (15%) | called by muse, mutect2, varscan2
- SLC35E2A | n.1091A>C | RNA (SNP) | VAF 26/404 reads (6%) | called by muse, mutect2
- SLC7A8 | c.508+10052G>C | Intron (SNP) | VAF 12/316 reads (4%) | called by muse, mutect2
- SOX17 | c.*31C>A | 3'UTR (SNP) | VAF 72/293 reads (25%) | called by muse, mutect2, varscan2
- SP5 | chr2:170713913 C>A | 5'Flank (SNP) | VAF 73/269 reads (27%) | called by muse, mutect2, varscan2
- SSPOP | n.4331_4351del | RNA (DEL) | VAF 92/415 reads (22%) | called by mutect2, pindel, varscan2
- ST3GAL5 | c.318+40C>G | Intron (SNP) | VAF 34/138 reads (25%) | called by muse, mutect2, varscan2
- SYP | c.103-46C>T | Intron (SNP) | VAF 52/149 reads (35%) | called by muse, mutect2, varscan2
- TBXT | c.*41G>T | 3'UTR (SNP) | VAF 19/263 reads (7%) | catalogued as rs756655657; called by muse, mutect2
- TRHDE | chr12:72271929 C>A | 5'Flank (SNP) | VAF 21/252 reads (8%) | called by muse, mutect2
- TRIP12 | c.99-924T>C | Intron (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- UNC119 | c.335-30C>T | Intron (SNP) | VAF 12/128 reads (9%) | catalogued as rs1459615019; called by muse, mutect2
- Unknown | chr7:55699033 G>A | IGR (SNP) | VAF 44/151 reads (29%) | called by muse, mutect2, varscan2
- XIST | n.8254C>T | RNA (SNP) | VAF 79/136 reads (58%) | called by muse, mutect2, varscan2
- ZNF211 | c.90+423A>G | Intron (SNP) | VAF 42/164 reads (26%) | catalogued as rs1378196235; called by muse, mutect2, varscan2
